Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB2F, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB2F-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

ICD-O-3
Liposarcoma, dedifferentiated
885813
Site Retroperitoneal
C48.0
Q. J 3/10/14

.....
Clinical Diagnosis & History:

with long left retroperitoneal mass extending from the spleen to pelvis seen on imaging

Specimens Submitted:

1: Soft tissue, left retroperitoneum (mass); excision

DIAGNOSIS:

1. Soft tissue mass left retroperitoneum, kidney, adrenal gland, spleen, portion of pancreas and segment of colon; excision:
- Dedifferentiated liposarcoma, arising in a background of well-differentiated liposarcoma.
- Tumor size: 27.0 x 27.0 x 13.0 cm.
- The dedifferentiated component predominates (>50%) and has a high grade malignant fibrous histiocytoma-like morphology.
- Tumor involves the renal capsule of the kidney, surface of adrenal gland, and subserosal fat of the colon.
- Tumor necrosis is identified (20-30%).
- The tumor is covered by a thin fibrous membrane, which represents the margin.
- Portion of unremarkable pancreas.
- Unremarkable spleen and kidney.
- One benign lymph node.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1) The specimen is received fresh, labeled "Left retroperitoneal mass", and

** Continued on next page **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2
consists of a gray-tan encapsulated mass of rubbery soft tissue measuring 27.0 x 27.0 x 13.0 cm, with gray-tan fibromembranous soft tissue and yellow-tan lobulated adipose tissue consistent with omentum. The portion of spleen measures 10.8 x 5.9 x 3.1 cm. The capsule is dull gray purple, and grossly unremarkable. Section reveals red-brown congested parenchyma. There is an attached portion of large bowel measuring 15.5 cm in length by 2.7 cm in diameter. The bowel displays a grey-tan smooth serosa, which is adherent to the encapsulated mass. The bowel is opened to reveal gray-tan plicated partially flattened mucosa, a wall averaging 0.4 cm in thickness. The mass is sectioned to reveal variegated grey-tan to yellow tan rubbery cut surfaces with focal hemorrhagic and gelatinous soft cut surfaces. A kidney is identified, measuring 9.0 x 6.1 x 4.3 cm. The ureter measures 18.0 cm in length by 0.6 cm in average diameter. The cortex measures 0.7 cm, and the corticomedullary junction appears unremarkable. The kidney parenchyma appears predominantly unremarkable. The mass appears adherent to the kidney capsule. There is an attached portion of orange tan adrenal gland measuring 3.0 x 2.4 x 1.0 cm. A portion of yellow-tan lobulated rubbery tissue measuring 2.9 x 1.8 x 0.9 cm is identified, consistent with pancreatic parenchyma. Representative sections are submitted. Gross photographs are taken. A portion is submitted for TPS. This case was discussed with Dr

Summary of sections:

UM - ureter margin
KT - kidney to tumor
BWT - bowel wall to tumor
ADT - adrenal to tumor
SPL - spleen
P - pancreas
T - tumor, representative
F - fat

Summary of Sections:

Part 1: Soft tissue, left retroperitoneum (mass); excision

Blocks	Block Designation	PCs
1	ADT 1	
2	BWT 2	
1	F 1	
3	KT 3	
1	P 1	
1	SPL 1	
8	T 16	
1	UM 1	

** End of Report **

Source: NCI Genomic Data Commons file 1d1d9eac-42a7-487d-a4c8-7c5dd34154b8 (TCGA-DX-AB2F.B863DB4E-A800-4674-AFBD-9B62BFAAD674.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).